Somatic mutation profile of tumor specimen C3N-03796-01 (aliquot CPT0285160006) from CPTAC case C3N-03796, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.9 years (20,425 days).
Specimen C3N-03796-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6699cce-ab02-4ea8-98f7-e0bb28d94a0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03796-31 (Blood Derived Normal), aliquot CPT0285170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11da895c-a877-4f36-915d-2c82083dccc3

The open-access MAF lists 125 somatic variants for this specimen: 81 protein-altering or splice-affecting, 29 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 29, 5'UTR 5, Nonsense Mutation 4, RNA 4, 3'UTR 3, Intron 3, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 66/105 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as rs1285960468; called by muse, mutect2, varscan2
- AACS | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.218); catalogued as rs769532481; called by muse, mutect2, varscan2
- ANO9 | c.833-8C>T | Splice Region (SNP) | VAF 66/173 reads (38%) | catalogued as rs201982234; called by muse, mutect2, varscan2
- ARID5B | c.1919A>G p.N640S | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs150157555; called by muse, mutect2, varscan2
- CCDC68 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 73/219 reads (33%) | catalogued as COSV61605150; called by muse, mutect2, varscan2
- COL2A1 | c.3133C>G p.P1045A | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as rs756815438; called by muse, mutect2, varscan2
- DENND2C | c.1342G>A p.E448K (on ENST00000393274 / NM_001256404.2; = p.E391K on NM_198459.4) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs536238659, COSV67921725; called by muse, mutect2, varscan2
- DNAH1 | c.3725G>A p.R1242Q | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs574664508, COSV70233011; called by muse, mutect2, varscan2
- DOCK2 | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758912789, COSV56968576; called by muse, mutect2, varscan2
- ELAPOR2 | c.1738C>T p.R580W (on ENST00000450689 / NM_001142749.3; = p.R413W on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs202199924, COSV51890798; called by muse, mutect2, varscan2
- FAM83H | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 143/391 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs868951670; called by muse, mutect2, varscan2
- FOXP2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 101/536 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1276471970, COSV63486447; called by muse, mutect2, varscan2
- GFRA3 | c.1026G>A p.T342= | Splice Region (SNP) | VAF 65/164 reads (40%) | catalogued as rs369291619; called by muse, mutect2, varscan2
- HMCN1 | c.3847C>T p.R1283C | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs781327521, COSV54944264; called by muse, varscan2
- ICA1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766630394; called by muse, mutect2, varscan2
- IGKV2D-30 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs375935817; called by muse, mutect2, varscan2
- IL27 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs201926026, COSV100113006, COSV60488600; called by muse, mutect2, varscan2
- JPH3 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 138/392 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs770238690, COSV52468933; called by muse, mutect2, varscan2
- KCNJ3 | c.1245A>T p.K415N | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); catalogued as COSV54538286; called by muse, mutect2, varscan2
- KCNQ5 | c.2269A>G p.I757V | Missense Mutation (SNP) | VAF 99/381 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1435559981; called by muse, mutect2, varscan2
- KIAA1755 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs768457929, COSV54079604; called by muse, mutect2, varscan2
- KRTAP4-2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 142/437 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs368267744; called by muse, mutect2, varscan2
- MASP2 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs141592611; called by muse, mutect2, varscan2
- MCOLN3 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.271); catalogued as rs144793042; called by muse, mutect2, varscan2
- MEGF11 | c.1298G>A p.C433Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201105131; called by muse, mutect2
- MUC17 | c.7675G>A p.A2559T | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs148952150; called by muse, mutect2, varscan2
- MYH4 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 121/208 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs987033458, COSV55123160; called by muse, mutect2, varscan2
- MYO15A | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV52763193; called by muse, mutect2
- NKD2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs188976018; called by muse, mutect2, varscan2
- NMBR | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769399701, COSV57801524; called by muse, mutect2, varscan2
- OR8G2P | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as rs201784816; called by muse, mutect2
- PCDHA2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 205/487 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV65364468; called by muse, mutect2, varscan2
- PLCG1 | c.2001-1G>A p.X667_splice | Splice Site (SNP) | VAF 61/154 reads (40%) | catalogued as rs6072292; called by muse, mutect2, varscan2
- R3HDML | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1242284163; called by muse, mutect2
- RELN | c.9463G>A p.V3155I | Missense Mutation (SNP) | VAF 128/731 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs769668891; called by muse, mutect2, varscan2
- RRP1B | c.2088C>G p.F696L | Missense Mutation (SNP) | VAF 129/412 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761948113; called by muse, mutect2, varscan2
- SERPINE1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 36/881 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV56169760, COSV56169835; called by muse, mutect2
- SLC7A3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 75/90 reads (83%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV53226643; called by muse, mutect2, varscan2
- ST8SIA2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 16/454 reads (4%) | PolyPhen probably damaging (1); catalogued as COSV51571289; called by muse, mutect2
- SV2B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs748998104, COSV57699202; called by muse, mutect2, varscan2
- TEDC1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as rs781843164; called by muse, mutect2, varscan2
- TENM3 | c.7733C>T p.T2578M | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs760930126, COSV69314886; called by muse, mutect2, varscan2
- THSD7B | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs200250890, COSV55707540; called by muse, mutect2, varscan2
- TTN | c.61441G>A p.E20481K (on ENST00000591111; = p.E13057K on NM_003319.4) | Missense Mutation (SNP) | VAF 149/406 reads (37%) | PolyPhen possibly damaging (0.475); catalogued as rs764747244; called by muse, mutect2, varscan2
- ZAN | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.553); catalogued as rs367593224; called by muse, mutect2, varscan2
- ZNF836 | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs762115893, COSV100441053; called by muse, mutect2, varscan2
- AOAH | c.1354A>T p.N452Y | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BCOR | c.4002T>A p.C1334* (on ENST00000378444 / NM_001123385.2; = p.C1300* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- BTAF1 | c.4448A>C p.E1483A | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C19orf57 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 138/234 reads (59%) | SIFT tolerated (0.94); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CYP46A1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- DNAH7 | c.10057G>T p.G3353* | Nonsense Mutation (SNP) | VAF 103/287 reads (36%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.7874T>C p.L2625S | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- EHD1 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FAM135B | c.394A>T p.M132L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM228A | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- GFI1B | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTPBP10 | c.671T>A p.I224K | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- INHBA | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JHY | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHX2 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- MISP | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MISP | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, varscan2
- MRGPRX1 | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NCF2 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2V1 | c.29C>G p.T10R | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, varscan2
- OR4A16 | c.247T>A p.L83I | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- OR52E4 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PARP14 | c.4853G>T p.C1618F | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PCDH11X | c.3335C>A p.P1112H | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPFIA2 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- PRX | c.2038C>A p.L680I | Missense Mutation (SNP) | VAF 208/558 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RB1 | c.1850del p.G617Vfs*6 | Frame Shift Del (DEL) | VAF 68/139 reads (49%) | called by mutect2, pindel, varscan2
- RPGRIP1 | c.3069C>A p.S1023R | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAA2-SAA4 | c.247A>C p.T83P | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- SLC30A7 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TOX2 | c.38T>A p.F13Y | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZC3H12C | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP91 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZNF527 | c.1349C>A p.T450N | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ABCB4 | c.912C>T p.A304= | Silent (SNP) | VAF 49/343 reads (14%) | called by muse, mutect2, varscan2
- ANK3 | c.10947G>A p.G3649= | Silent (SNP) | VAF 57/80 reads (71%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1428T>A p.T476= | Silent (SNP) | VAF 22/32 reads (69%) | called by muse, varscan2
- BPIFA2 | c.417C>T p.I139= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV53611296; called by muse, mutect2, varscan2
- CCDC185 | c.441G>A p.P147= | Silent (SNP) | VAF 59/181 reads (33%) | catalogued as rs751685838, COSV64820624; called by muse, mutect2, varscan2
- CELF5 | c.144C>T p.F48= | Silent (SNP) | VAF 66/460 reads (14%) | catalogued as COSV53011147; called by muse, mutect2, varscan2
- CNTN4 | c.1932A>T p.A644= | Silent (SNP) | VAF 101/296 reads (34%) | called by muse, mutect2, varscan2
- COG4 | c.1662C>T p.N554= | Silent (SNP) | VAF 152/462 reads (33%) | catalogued as rs778700990; called by muse, mutect2, varscan2
- DBX1 | c.726C>T p.R242= | Silent (SNP) | VAF 140/394 reads (36%) | catalogued as COSV57054462; called by muse, mutect2, varscan2
- DENND2B | c.1269C>T p.P423= | Silent (SNP) | VAF 87/218 reads (40%) | catalogued as COSV58205143; called by muse, mutect2, varscan2
- DOHH | c.882G>A p.L294= | Silent (SNP) | VAF 157/767 reads (20%) | catalogued as rs1489056567; called by muse, mutect2, varscan2
- FANCA | c.1980G>A p.L660= | Silent (SNP) | VAF 110/311 reads (35%) | called by muse, mutect2, varscan2
- GHSR | c.1089T>C p.S363= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs1485998331; called by muse, mutect2, varscan2
- ITGBL1 | c.771G>A p.P257= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs145784947; called by muse, mutect2, varscan2
- MED22 | c.312G>A p.Q104= | Silent (SNP) | VAF 44/422 reads (10%) | called by muse, mutect2
- MISP | c.351G>A p.E117= | Silent (SNP) | VAF 160/755 reads (21%) | catalogued as COSV53121604; called by muse, varscan2
- MLYCD | c.354G>A p.E118= | Silent (SNP) | VAF 80/212 reads (38%) | catalogued as rs1194397409; called by muse, mutect2, varscan2
- MNX1 | c.732G>A p.P244= | Silent (SNP) | VAF 47/261 reads (18%) | called by muse, mutect2, varscan2
- NCF4 | c.123C>T p.F41= | Silent (SNP) | VAF 127/328 reads (39%) | catalogued as rs369350039; called by muse, mutect2, varscan2
- OR7A10 | c.840G>T p.V280= | Silent (SNP) | VAF 31/235 reads (13%) | called by muse, mutect2
- PCDH10 | c.585G>A p.A195= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV52105801; called by muse, mutect2, varscan2
- PRPF8 | c.2715C>T p.L905= | Silent (SNP) | VAF 165/284 reads (58%) | catalogued as rs878916133, COSV59260592; called by muse, mutect2, varscan2
- PTPN3 | c.2643C>T p.R881= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as rs751829166; called by muse, mutect2, varscan2
- RHOBTB2 | c.1659C>T p.A553= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs779817867, COSV52572008; called by muse, mutect2, varscan2
- RYR2 | c.7374G>A p.A2458= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs780891381, COSV100772029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIPA1 | c.1635C>G p.T545= | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- TMC2 | c.558G>A p.E186= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as rs1246668796; called by muse, mutect2, varscan2
- TRAV5 | c.24G>A p.S8= | Silent (SNP) | VAF 78/221 reads (35%) | catalogued as rs367799949; called by muse, mutect2, varscan2
- WRAP73 | c.648G>A p.T216= | Silent (SNP) | VAF 57/231 reads (25%) | catalogued as rs199577838; called by muse, mutect2
- AGAP7P | n.2040G>A | RNA (SNP) | VAF 58/302 reads (19%) | called by muse, mutect2, varscan2
- C5orf38 | c.*55G>A | 3'UTR (SNP) | VAF 34/74 reads (46%) | catalogued as rs1380424426, COSV57411870; called by muse, mutect2, varscan2
- CNDP1 | c.-30del | 5'UTR (DEL) | VAF 51/150 reads (34%) | called by mutect2, pindel, varscan2
- ELANE | c.-7C>T | 5'UTR (SNP) | VAF 108/498 reads (22%) | called by muse, mutect2, varscan2
- EXTL3 | c.-518_-517del | 5'UTR (DEL) | VAF 60/209 reads (29%) | called by mutect2, pindel, varscan2
- FAM183BP | n.592C>T | RNA (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- GABRB3 | c.241-7478C>T | Intron (SNP) | VAF 63/289 reads (22%) | catalogued as rs574116332; called by muse, mutect2, varscan2
- GML | c.-8G>A | 5'UTR (SNP) | VAF 57/140 reads (41%) | catalogued as rs375561355; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2385G>A | RNA (SNP) | VAF 129/817 reads (16%) | called by muse, mutect2, varscan2
- IDO1 | c.537+11C>A | Intron (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- RSPO1 | c.-44C>T | 5'UTR (SNP) | VAF 132/331 reads (40%) | catalogued as rs750153109, COSV100740474; called by muse, mutect2, varscan2
- RUNX1 | c.*18G>A | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- SHROOM3 | c.4710-22T>C | Intron (SNP) | VAF 52/120 reads (43%) | called by muse, mutect2, varscan2
- SLIT2 | c.*1442del | 3'UTR (DEL) | VAF 15/66 reads (23%) | catalogued as COSV56561142; called by mutect2, pindel, varscan2
- SSTR5-AS1 | n.580G>A | RNA (SNP) | VAF 40/99 reads (40%) | catalogued as rs184789215; called by muse, mutect2, varscan2
